Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8K1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8K1-06A (Metastatic).

[page 1 of 7]
Surgical Histology
Surgical Histology

Copy To: Cancer Registry

HISTOPATHOLOGY REPORT

***SUPPLEMENTARY REPORT Dated:

ICD-0-3
Melanoma, superficial spreading 8748/3
Site R calf subcutaneous tissue
049.2
JUN 11/22/13

CASE HISTORY:

year history of flat pigmented lesion. Traumatic scratch
Nodule appeared. ?pigmented BCC

MACROSCOPIC:

Skin ellipse, 4.3 x 2.2cm, bearing a nodular mass, 1.1 x 0.8cm. The superior half is mainly brown, and the inferior half, mainly grey. With the marker suture at 12'o'clock, the 3'o'clock edge is painted green and the 9'o'clock edge, blue. A = superior, B = inferior.

MICROSCOPY:

This is a malignant melanoma. Although the main mass is nodular, small junctional nests in adjacent epidermis suggest that it is of superficial spreading type. However similar morphology may be seen in epidermotropic metastasis.

TUMOUR TYPE: Superficial spreading

GROWTH PHASE: vertical

BRESLOW THICKNESS: 1.8mm (please see supplementary)

ULCERATION: present (1.5mm diameter)

LYMPHOVASCULAR INVASION: absent

PERINEURAL INVASION: absent

REGRESSION: absent

MICROSATELLITES: A focus of in transit metastasis is present (1.5mm diameter)

CO-EXISTENT NAEVUS: absent

MITOTIC RATE: 5 mitosis in 1 mm square

TUMOUR INFILTRATING LYMPHOCYTES: absent

EXCISION MARGINS:

Deep: 0.9mm from microsatellite; 5mm from main tumour

Circumferential: 2mm from microsatellite; 6mm from main tumour

STAGE: pT2b

DIAGNOSIS:

EXCISION, RIGHT CALF: MALIGNANT MELANOMA

REPORTED BY:

REPORT DATE:

***SUPPLEMENTARY REPORT Dated:

[page 2 of 7]
SUPPLEMENTARY REPORT:

Please note that the Breslow thickness is 3mm and not 1.8mm as originally stated. This alters the stage to pT3b.

STAGE: pT3b

DIAGNOSIS:

EXCISION, RIGHT CALF: MALIGNANT MELANOMA

DATED

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: Plastic Surgery

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

pT3b melanoma right calf wider excision. 2 x sentinel nodes excised right groin.

MACROSCOPIC:

Previous report indicates margins are clear of superficial spreading melanoma with microsattelites.

1. Skin ellipse with a stitch indicating superior from the propose of this macroscopy is it designated 12'o'clock and its at the tip. Skin ellipse measures 12 x 35 x 9mm and bares a well healed linear scar 40mm. Three nodules identified macroscopically, the largest 9mm in diameter. 3'o'clock margin inked red, D and E = one TS, A = one TS, B and C = nodes identified in subcutaneous tissue, not complete TSs.
2. Firm fibrofatty nodular tissue 28 x 20 x 5mm.
3. Fibrofatty nodule 20 x 12 x 6mm containing a lymph node.

MICROSCOPY:

1. Melanoma right calf stitched superior: Shows skin in which there is scar tissue formation associated with three separate residual satellite nodules of malignant melanoma seen at the junction of the deep dermis and subcutis. All nodules do not involve the epidermis and therefore are best regarded as satellite nodules as seen in the original resection specimen. The satellite nodules are associated with lymphovascular invasion and are situated in subcutaneous tissue and not within lymph nodes. Furthermore the largest satellite

[page 3 of 7]
nodule is 9mm in diameter and removed on deep margin by 7mm. The second largest has a maximum diameter of 6mm and removed on the deep margin by 11mm and the smallest satellite nodule has a maximum diameter of 4mm and removed on deep margin by 10mm. All satellite nodules therefore appeared to be fully removed.

2. Sentinel lymph node 1, right groin: Shows lymph node tissue in which there is prominent fibrosis and fatty infiltration. No metastatic melanoma could be found within this lymph node tissue.

3. Sentinel lymph node 2, right groin: Shows lymph node tissue in which there is also fibrosis and fat infiltration. No metastases was seen.

DIAGNOSIS:

1. SKIN (RIGHT CALF, WIDE EXCISION): THREE RESIDUAL SATELLITE NODULES OF MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE; PLEASE SEE ABOVE.

2. SENTINEL LYMPH NODE 1, RIGHT GROIN: FIBROSIS AND FATTY INFILTRATION ONLY.

3. SENTINEL LYMPH NODE 2, RIGHT GROIN: LYMPH NODE SHOWING REACTIVE CHANGE WITH FAT INFILTRATION.

REPORTED BY:

REPORT DATE:

AMENDED REPORT

These slides were reviewed for

On review of specimen two (labelled sentinel node one, right groin), isolated groups of cells within the cortex and capsule of the lymph node were found, which stained positively for HMB45 as well as S100.

These findings are therefore regarded as early metastases within sentinel lymph node number one.

On review of specimens one and three, show features as previously reported.

FINAL DIAGNOSIS:

SENTINEL LYMPH NODE ONE (RIGHT GROIN) (SPECIMEN TWO): EARLY METASTATIC MALIGNANT MELANOMA.

REPORTED BY:

Surgical Histology

Surgical Histology

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

[page 4 of 7]
CASE HISTORY:

Positive sentinel node for melanoma

MACROSCOPIC:

1. Lateral lymph node? Fat 2 cm including a 1 cm firm grey nodule.
2. Skin ellipse 13 x 3 cm with a 7 cm scar. A suture is present. 2A and 2B = sutured area. C = previous biopsy site.

MICROSCOPY:

1. Lymph node with no evidence of metastatic melanoma
2. Three lymph node identified which are negative for metastatic tumour. However malignant melanoma is present within an occluded vessel, probably a lymphatic, and apparently unrelated to a lymph node. The proximity of this to the surgical margins is not possible to ascertain

DIAGNOSIS:

LEFT GROIN: INTRAVASCULAR MALIGNANT MELANOMA, SEE ABOVE

REPORTED BY:

Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT: Plastic Surgery

CYTOPATHOLOGY REPORT

CASE HISTORY:

? metastatic melanoma.

MACROSCOPIC:

3 air dried slides dated
Error logged 2 of 3 slides with material on the wrong side, no location on form

MICROSCOPY:

This is a highly cellular sample containing short spindle cells (fibroblast like) with admixed oval and elongated cells with highly atypical nuclei and prominent nucleoli. Focally there are cells with fine dusky pigment.

Immunostain for a melanocytic marker was attempted, but this was unsuccessful.

Overall, in the appropriate clinical context the features would support the diagnosis of malignant melanoma.

[page 5 of 7]
DIAGNOSIS:

FNA OF NODULE RIGHT THIGH: MALIGNANT CELLS PRESENT; SEE TEXT.

REPORTED BY:

Histopathology
Consultant Histopathologist

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

****SUPPLEMENTARY REPORT**

CASE HISTORY:

Previous malignant melanoma on right calf. Now has black nodules that this site

MACROSCOPIC:

1. Piece of connective tissue, 2.5 x 1 x 2cm. On slicing it contains numerous black nodules, up to 1 cm in maximum extent. Also present in the specimen container is a skin ellipse, 1 x 0.2cm with underlying tissue to a depth of 0.5cm.
2. Polypoid piece of tissue, 1cm in maximum extent.

MICROSCOPY:

1. Skin with subcutaneous nodules of malignant melanoma showing central necrosis.
The features are in keeping with completely replaced lymph nodes in some of the larger nodules. Tumour extends very close to excision margins.
2. Subcutaneous tissue with a well circumscribed nodule of malignant melanoma which extends to excision margins. This may represent a completely replaced lymph node

DIAGNOSIS:

1 & 2 LYMPH NODES RIGHT CALF: METASTATIC MALIGNANT MELANOMA

REPORTED BY:

[page 6 of 7]
SUPPLEMENTARY REPORT:
BRAF immunostain is negative.

REPORTED BY:

SUPPLEMENTARY REPORT:
The case was sent to . for BRAF
testing.

Real time PCR analysis of the BRAF gene has revealed NO MUTATIONS
within codon 600 of the BRAF gene.

MELANOMA: NO EVIDENCE OF MUTATION WITHIN CODON 600 OF BRAF.

REPORTED BY:

Surgical Histology

Surgical Histology

Supplementary report
ADDRESS FOR REPORT:
Copy To: n/a
Report to Cancer Registry

HISTOPATHOLOGY REPORT

CASE HISTORY:

Lesion Right thigh. Metastatic melanoma. Specimen has been tissue
banked and area has been inked.

MACROSCOPIC:

An ellipse of skin with underlying fatty tissue. Ellipse measures
6.5 x 3 cm. Entire specimen measures 6.5 x 6 x 2 cm. Deep margin
has been disrupted due to Tissue Banking. Tumour was seen through
aperture on deep margin measuring 2.5 x 2 cm.

MICROSCOPY:

Microscopic examination of the specimen from the right thigh shows
skin with underlying lymph nodes in which the features of metastatic
melanoma. No metastasis was seen with in the skin however within the
underlying tissues and metastatic melanoma was found in at least 4
lymph nodes. The maximum diameter of subcutaneous melanoma is 16 mm
in which this lymph node shows a tumour necrosis as well as
extracapsular extension.

The deep margin of the specimen has been disrupted due to tissue
banking before receipt however tumour appears to be fully removed by
0.3 mm on the deep margin.

DIAGNOSIS:

SKIN AND SUBCUTIS RIGHT THIGH: METASTATIC MELANOMA.

[page 7 of 7]
REPORTED BY:

REPORT DATE:

Supplementary report:

Immunohistochemistry for BRAF mutation was done on request. This showed negative staining.

Source: NCI Genomic Data Commons file 705552d9-7956-4f12-b821-f70d4533e5a1 (TCGA-WE-A8K1.3BB08AA2-7C56-4C47-B587-400C73DA930E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).